TARGET case TARGET-30-PAIRLD — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/61908bd7-8d75-56db-a005-5d0a8b1052c8

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Age at diagnosis: 4.7 years (1,715 days); Year of diagnosis: 1998; Days to last follow up: 596 days (1.6 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PAIRLD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
